Surgical pathology report (de-identified scan), TCGA case TCGA-J9-A52E, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Melbourne Health, specimen TCGA-J9-A52E-01A (Primary Tumor).

[page 1 of 2]
HISTOPATHOLOGY REPORT

CLINICAL NOTES :

PSA 2.7, Gleason 9 both sides, T2c. Tissue banking. Previous biopsy

MACROSCOPIC :

Specimen 1: A 49 g radical prostate, 50 x 48 x 45 mm

Block designation:

Block AB Right apex Block C to F Left apex

Block G to K Right base Block L to O Left base

Blocks P to S Apex to base right, side blue Blocks T to W Apex to base left side green

Specimen 2: Posterior bladder neck, tissue six by five by 3 mm

Specimen 3: Right pelvic lymph node, fatty tissue containing five lymph nodes

Specimen 4: Left pelvic lymph node, the fatty tissue containing three lymph nodes ATP sl

MICROSCOPIC :

The sections show extensive multifocal, bilateral adenocarcinoma. The index tumour is a bilateral peripheral zone tumour Gleason pattern **4+5=9** with extraprostatic lymphovascular invasion and widespread perineural infiltration. There is invasion of both seminal vesicles, greater on the left side and tumour directly invades the ejaculatory duct on the left side.

There is widespread, multifocal extraprostatic extension involving direct and perineural spread;

at the right apex, 10 mm in greatest dimension with clear overlying pathological margin;

at the right apex (separate transition zone focus, Gleason patterns **3+3=6**), 2mm, with 2 mm positive pathological margin;

at the right bladder neck, 18 mm, with a 6 mm positive pathological margin with significant diathermy change;

at the left bladder neck, 10 mm, associated with 6 mm positive pathological margin, again with diathermy change;

right lateral aspect, 12 mm in dimension, overlying pathological margins are clear;

and right posterior 22 mm, overlying pathological margins are clear.

The posterior bladder neck biopsy contains bladder neck muscle and extensive high grade tumour.

The right pelvic lymph nodes (5) and the left pelvic lymph nodes (3) are unremarkable with no evidence of metastatic malignancy.

Tissue banking correctly identified

CONCLUSION:

Robotic radical prostatectomy and bilateral lymph nodes -- Extensive multifocal, bilateral adenocarcinoma. Index tumour bilateral Gleason 4+5=9 with bilateral positive seminal vesicles, widespread bilateral extraprostatic extension, and multifocal extensive positive pathological margins, lymph nodes negative, pT3bN0.

SYNOPTIC REPORT: CARCINOMA OF PROSTATE

Specimen type : Robotic radical prostatectomy and bilateral lymph nodes -- tissue banking

Tumour type: Index tumour: adenocarcinoma nos

Other tumour foci: transition zone

Gleason score: Index tumour: 4+5=9

Other tumour foci: 3+3=6

Site: See volumetric analysis.

Unifocal/Multifocal : multifocal

Perineural invasion : present intra an extra prostatic

Lymphovascular invasion : present

100-0-3
Path: adenocarcinoma, NOS 8140/3
cGUP: adenocarcinoma, acinar 8550/3
Site: prostate, NOS 061.9

11/12/12

AA Discrepancy		

[page 2 of 2]
Extraprostatic extension : present Multifocal bilateral

Seminal vesicle involvement : positive bilateral

Pathological resection margin status : positive multifocal bilateral extensive

Presence of PIN : moderate

Lymph nodes: Site Bilateral obturator
Number of nodes present Right 5 Left 3
Number of nodes positive 0
Extranodal extension not identified

Tumour Volume: Peripheral Zone (black): 17.6cc
Transition Zone (green): 0.2cc

Pathologic stage: pT3bN0

Reported by: Dr

Source: NCI Genomic Data Commons file 4e27f7e1-532a-428b-9dcb-45cc0f721700 (TCGA-J9-A52E.5154D45B-244F-45B1-BE2F-9C02716B1CB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).